Somatic mutation profile of tumor specimen TCGA-GK-A6C7-01A (aliquot TCGA-GK-A6C7-01A-11D-A33K-10) from TCGA case TCGA-GK-A6C7, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.0 years (28,107 days).
Specimen TCGA-GK-A6C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2954a819-85f0-4012-a3b4-aea46ffce160.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GK-A6C7-10B (Blood Derived Normal), aliquot TCGA-GK-A6C7-10B-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc5316dd-26cd-45e3-88b8-01a68bea9624

The open-access MAF lists 104 somatic variants for this specimen: 83 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Frame Shift Del 9, Nonsense Mutation 7, Frame Shift Ins 5, Splice Region 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WDR35 | c.3459G>T p.W1153C (on ENST00000345530 / NM_001006657.2; = p.W1142C on NM_020779.4) | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1553313859, CM162451, COSV99853590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL136295.1 | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV99938365; called by muse, mutect2
- ALB | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV55737902, COSV55739019; called by muse, mutect2, varscan2
- AMOTL2 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99998370; called by muse, mutect2, varscan2
- BAZ1B | c.3631C>A p.L1211M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV100290219; called by muse, mutect2, varscan2
- BMP1 | c.2199C>A p.F733L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV100110242, COSV60479707; called by muse, varscan2
- CCDC125 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV101143772; called by muse, mutect2, varscan2
- CEACAM3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV55760805; called by muse, mutect2, varscan2
- CENPF | c.4016T>G p.V1339G | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100872071; called by muse, mutect2, varscan2
- CEP76 | c.1724G>A p.G575D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100043054; called by muse, mutect2, varscan2
- COCH | c.33C>T p.L11= | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99363996; called by muse, mutect2, varscan2
- CYB5R2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100207610; called by muse, mutect2, varscan2
- CYP4A22 | c.248del p.P83Qfs*23 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | catalogued as COSV99594604; called by mutect2, pindel, varscan2
- DNAH9 | c.6087G>T p.L2029F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99308696; called by muse, mutect2, varscan2
- EFCAB7 | c.798A>C p.L266F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs753835859, COSV100937734; called by muse, mutect2, varscan2
- EPPK1 | c.5714C>T p.P1905L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV101599981; called by muse, mutect2, varscan2
- ESYT1 | c.2205A>T p.K735N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV99920398; called by muse, mutect2, varscan2
- FAM184A | c.1175C>A p.T392N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100138442; called by muse, mutect2, varscan2
- GGA3 | c.2041T>A p.L681M (on ENST00000537686 / NM_138619.4; = p.L648M on NM_014001.5) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99822405; called by muse, mutect2, varscan2
- GLMN | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 34/155 reads (22%) | catalogued as rs751393940, CM137077, COSV100950225; called by muse, mutect2, varscan2
- GNB1 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV101060875; called by muse, mutect2, varscan2
- GRAMD1A | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58765841; called by muse, mutect2, varscan2
- HCN4 | c.2067C>A p.F689L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99984355; called by muse, mutect2, varscan2
- HSP90AA1 | c.1453A>G p.K485E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs201678802, COSV99355581; called by muse, mutect2, varscan2
- KAT2A | c.1729G>T p.V577F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99288598; called by muse, mutect2, varscan2
- KIF4A | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100979664; called by muse, mutect2, varscan2
- KMT2D | c.3755G>T p.R1252L | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs753048826, COSV99986452; called by muse, mutect2, varscan2
- KRT4 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV53408912, COSV99543283; called by muse, mutect2, varscan2
- LRRC15 | c.816C>G p.N272K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV100752982; called by muse, mutect2
- LRWD1 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99484615; called by muse, mutect2, varscan2
- LY6G5C | c.580_581insA p.R195Pfs*22 (on ENST00000375863; = p.R120Pfs*22 on NM_025262.3) | Frame Shift Ins (INS) | VAF 19/90 reads (21%) | catalogued as COSV101020867; called by mutect2, pindel, varscan2
- MAB21L4 | c.571T>C p.S191P (on ENST00000388934 / NM_001085437.3; = p.S23P on NM_024861.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100278735; called by muse, mutect2, varscan2
- MRI1 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99237903; called by muse, mutect2, varscan2
- MRPL17 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996950; called by muse, mutect2, varscan2
- MRPS31 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100062551; called by muse, mutect2, varscan2
- MSANTD4 | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100108681; called by muse, mutect2
- MYH10 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99346562; called by muse, mutect2
- NAA35 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100863467; called by muse, mutect2, varscan2
- NAA35 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100863468; called by muse, mutect2, varscan2
- NOS1 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100501560; called by muse, mutect2, varscan2
- OR4D6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55658966; called by muse, mutect2, varscan2
- OR8J3 | c.877A>G p.R293G | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100041088; called by muse, mutect2, varscan2
- OTOA | c.1541C>T p.A514V (on ENST00000286149; = p.A500V on NM_144672.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs141037250, COSV53752301; called by muse, mutect2, varscan2
- PBRM1 | c.1720A>T p.N574Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99971349; called by muse, mutect2, varscan2
- PCDH17 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.784); catalogued as COSV100932152; called by muse, mutect2, varscan2
- PCDHA6 | c.844A>C p.N282H | Missense Mutation (SNP) | VAF 162/380 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV100972614; called by muse, mutect2, varscan2
- PCDHB13 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 162/409 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554287643, COSV99507978; called by muse, mutect2, varscan2
- PCNX2 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV50820624; called by muse, mutect2, varscan2
- PHLPP2 | c.2967A>C p.E989D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as COSV100673869; called by muse, mutect2, varscan2
- PJA1 | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV100824840; called by muse, mutect2, varscan2
- PLCL1 | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1278187587, COSV70876257; called by muse, mutect2
- PREPL | c.1915A>G p.I639V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs1341895350, COSV99576548; called by muse, mutect2, varscan2
- PRF1 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs140385034; called by muse, mutect2, varscan2
- SFXN3 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99827617; called by muse, mutect2
- SLC7A5 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99879549; called by muse, mutect2, varscan2
- SMTN | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs748966600, COSV100295012; called by muse, mutect2, varscan2
- SPART | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV100768887; called by muse, mutect2, varscan2
- SPATA21 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100131451; called by muse, mutect2, varscan2
- SPHK2 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99709688; called by muse, mutect2, varscan2
- SRRM2 | c.6586C>T p.P2196S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs781619820, COSV51942123; called by muse, mutect2, varscan2
- STAB2 | c.4129G>C p.G1377R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV101186445; called by muse, mutect2, varscan2
- STRC | c.3679C>T p.L1227= | Splice Region (SNP) | VAF 96/353 reads (27%) | catalogued as rs752685474, COSV101372255; called by muse, mutect2, varscan2
- TEX14 | c.2188G>T p.E730* (on ENST00000240361 / NM_001201457.2; = p.E724* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV99543877; called by muse, mutect2, varscan2
- TOR1AIP2 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.136); catalogued as COSV100857560; called by muse, mutect2, varscan2
- VAPA | c.741C>G p.F247L (on ENST00000400000 / NM_194434.3; = p.F292L on NM_003574.6) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.931); catalogued as COSV100486197; called by muse, mutect2, varscan2
- WASL | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.857); catalogued as COSV99771896; called by muse, mutect2, varscan2
- XIRP2 | c.749C>T p.T250I (on ENST00000628543; = p.T425I on NM_152381.6) | Missense Mutation (SNP) | VAF 9/304 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99748514; called by muse, mutect2
- ZNF518A | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1341407969, COSV100283782; called by muse, mutect2
- ZNF761 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV100483512, COSV61888966; called by muse, mutect2, varscan2
- ZNF800 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99758080; called by muse, mutect2, varscan2
- ZXDB | c.1200C>A p.C400* | Nonsense Mutation (SNP) | VAF 61/260 reads (23%) | catalogued as COSV100886088; called by muse, mutect2, varscan2
- ARID1A | c.2840del p.P947Hfs*21 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- CA12 | c.53del p.K18Rfs*10 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.681del p.Q227Hfs*10 | Frame Shift Del (DEL) | VAF 23/122 reads (19%) | called by mutect2, pindel, varscan2
- G3BP2 | c.1417dup p.M473Nfs*51 | Frame Shift Ins (INS) | VAF 34/112 reads (30%) | called by mutect2, pindel, varscan2
- GIMAP7 | c.243_247del p.I81Mfs*62 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel*, varscan2
- PISD | c.858_859insT p.V287Cfs*16 (on ENST00000439502 / NM_001326412.1; = p.V253Cfs*16 on NM_014338.3) | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel*, varscan2
- PLCL1 | c.2844del p.D949Tfs*20 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- POC5 | c.489dup p.D164* (on ENST00000428202 / NM_001099271.2; = p.D139* on NM_152408.2) | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- SLC16A10 | c.980del p.N327Ifs*30 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- TAF1C | c.1315dup p.L439Pfs*114 | Frame Shift Ins (INS) | VAF 34/105 reads (32%) | called by mutect2, pindel, varscan2
- WDR7 | c.2900del p.D967Afs*13 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- ZNF618 | c.1275_1284del p.Q426Rfs*6 (on ENST00000374126 / NM_001318042.2; = p.Q333Rfs*6 on NM_133374.2) | Frame Shift Del (DEL) | VAF 32/147 reads (22%) | called by mutect2, pindel, varscan2
- ACSM3 | c.1470A>C p.P490= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV99185109; called by muse, mutect2, varscan2
- ASPM | c.7431A>G p.L2477= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs778768318, COSV99661284; called by muse, mutect2, varscan2
- CEACAM20 | c.43C>T p.L15= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs764196654, COSV100387061; called by muse, mutect2, varscan2
- DMXL2 | c.663T>A p.S221= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV99198807; called by muse, mutect2, varscan2
- HEATR1 | c.651G>A p.L217= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1238683610, COSV100857824; called by muse, mutect2, varscan2
- HYDIN | c.7626G>A p.L2542= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV59254300; called by muse, mutect2, varscan2
- ITPRID1 | c.2062C>T p.L688= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs763405857, COSV100087776, COSV60082312; called by muse, mutect2, varscan2
- LGI1 | c.765T>G p.P255= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV101004498; called by muse, mutect2, varscan2
- MAP3K9 | c.2494C>T p.L832= (on ENST00000554752 / NM_001284230.1; = p.L846= on NM_033141.4) | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV67121167; called by muse, mutect2, varscan2
- NOS1AP | c.1176G>T p.T392= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100723673; called by muse, mutect2, varscan2
- PCDHB15 | c.1470G>T p.L490= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99179294; called by muse, mutect2, varscan2
- PCDHB15 | c.1471C>T p.L491= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99179297; called by muse, mutect2, varscan2
- PHF23 | c.600G>C p.R200= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99138964; called by muse, mutect2, varscan2
- SLC5A8 | c.33G>C p.V11= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101610620; called by muse, mutect2, varscan2
- SLC9A3 | c.1011C>T p.Y337= | Silent (SNP) | VAF 97/222 reads (44%) | catalogued as COSV99376609; called by muse, mutect2, varscan2
- TTN | c.77415T>C p.A25805= (on ENST00000591111; = p.A18381= on NM_003319.4) | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100634291; called by muse, mutect2, varscan2
- XRCC1 | c.543C>T p.S181= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs146426015; called by muse, mutect2, varscan2
- ZNF782 | c.102A>G p.R34= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV100001688; called by muse, mutect2, varscan2
- ZRANB3 | c.2994G>A p.K998= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs760565761, COSV99925057; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446203 C>G | 3'Flank (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- GABRE | c.784+1183G>T | Intron (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100944422; called by muse, mutect2
